Gene-level copy-number profile of tumor specimen ALCH-AE98-TTP1-A from ALCHEMIST case ALCH-AE98, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.0 years (20,072 days).
Specimen ALCH-AE98-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7b33f8b8-f4ac-495c-bcc5-e6a9ce6d0b88.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE98-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/0922665c-dc69-4e06-97ea-cb346c01ae75

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 113; copy number 1: 1,315; copy number 2: 55,431; copy number 3: 1,404; copy number 4: 111; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 110 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:911,435–921,016, 3 genes (within-gene range 0–2): AL645608.2, AL645608.4, LINC02593.
- chr1:966,482–982,093, 2 genes: PLEKHN1, PERM1.
- chr1:1,430,539–1,442,882, 2 genes: LINC01770, VWA1.
- chr1:3,712,200–3,714,298, 1 gene (within-gene range 0–2): TP73-AS2.
- chr1:16,035,178–16,057,308, 2 genes: AL355994.2, CLCNKB.
- chr1:43,991,500–44,031,467, 1 gene (within-gene range 0–2): SLC6A9.
- chr3:48,636,463–48,672,733, 4 genes: CELSR3, MIR4793, LINC02585, AC141002.1.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr7:1,530,702–1,560,821, 2 genes: MAFK, TMEM184A.
- chr7:5,526,409–5,563,902, 3 genes (within-gene range 0–2): ACTB, AC006483.2, AC006483.1.
- chr9:136,483,495–136,546,048, 4 genes (within-gene range 0–1): C9orf163, NOTCH1, MIR4673, AL592301.1.
- chr9:136,830,957–136,860,799, 4 genes (within-gene range 0–1): MIR4292, AJM1, PHPT1, MAMDC4.
- chr10:23,343,957–23,345,181, 1 gene (within-gene range 0–2): AL606469.1.
- chr10:133,344,643–133,350,726, 2 genes (within-gene range 0–1): BANF1P2, AL360181.1.
- chr10:133,355,158–133,358,025, 1 gene: FUOM.
- chr11:554,850–560,738, 2 genes (within-gene range 0–1): LMNTD2, LMNTD2-AS1.
- chr11:1,838,981–1,892,267, 6 genes (within-gene range 0–1): TNNI2, LSP1, MIR4298, AC051649.1, MIR7847, PRR33.
- chr11:2,159,779–2,171,815, 2 genes (within-gene range 0–1): INS, TH.
- chr11:2,899,721–2,929,420, 2 genes (within-gene range 0–2): SLC22A18, PHLDA2.
- chr12:132,489,551–132,593,698, 5 genes: FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1.
- chr13:113,815,630–113,845,744, 1 gene (within-gene range 0–2): GAS6-AS1.
- chr14:103,100,144–103,137,439, 3 genes: EXOC3L4, LINC00677, TNFAIP2.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr14:105,140,982–105,181,323, 4 genes: JAG2, MIR6765, AL512356.1, NUDT14.
- chr14:105,467,793–105,470,617, 1 gene (within-gene range 0–1): AL928654.2.
- chr15:78,759,206–78,811,464, 1 gene (within-gene range 0–2): ADAMTS7.
- chr16:1,064,093–1,078,731, 2 genes: SSTR5-AS1, AC009041.2.
- chr16:1,148,224–1,148,754, 1 gene: AC120498.8.
- chr16:1,431,078–1,444,556, 3 genes: PERCC1, CCDC154, AL032819.2.
- chr16:1,445,343–1,452,653, 2 genes (within-gene range 0–1): AL031600.3, AL031600.1.
- chr16:2,682,523–2,720,551, 3 genes (within-gene range 0–5): KCTD5, AC092117.2, PRSS27.
- chr16:4,314,761–4,339,597, 2 genes (within-gene range 0–1): GLIS2, GLIS2-AS1.
- chr16:4,335,870–4,337,818, 1 gene (within-gene range 0–1): AC012676.1.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:18,244,815–18,266,552, 2 genes (within-gene range 0–2): FLII, MIEF2.
- chr17:81,976,807–82,098,294, 11 genes: ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN.
- chr20:62,307,955–62,367,312, 3 genes (within-gene range 0–2): LAMA5, MIR4758, LAMA5-AS1.
- chr22:21,652,270–21,700,015, 9 genes (within-gene range 0–2): AP000553.1, MIR301B, MIR130B, AP000553.5, AP000553.6, AP000553.7, AP000553.4, AP000553.2, PPIL2.
- chr22:50,274,979–50,327,012, 4 genes: PLXNB2, DENND6B, CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,357,033–167,384,510, 1 gene, copy number 5 (within-gene range 2–5): TCP10L3.
- chr16:2,660,348–2,682,379, 1 gene, copy number 5: ERVK13-1.
- chr16:87,383,953–87,404,779, 2 genes, copy number 5 (within-gene range 3–5): MAP1LC3B, AC010531.3.

Autosomal genes at a single copy (total copy number 1): 1,264. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
